Somatic mutation profile of tumor specimen TCGA-55-6983-01A (aliquot TCGA-55-6983-01A-11D-1945-08) from TCGA case TCGA-55-6983, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB.
Specimen TCGA-55-6983-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c272376-5384-4ce1-877f-792d9732b04d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-6983-11A (Solid Tissue Normal), aliquot TCGA-55-6983-11A-01D-1945-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26d7b691-e994-4667-a0d9-38f1bb86e484

The open-access MAF lists 114 somatic variants for this specimen: 92 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 20, Nonsense Mutation 7, Frame Shift Del 4, Intron 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KATNB1 | c.97G>T p.G33W | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730880259, CM1413086, COSV65560188; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ABCB5 | c.1294C>A p.Q432K | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.364); catalogued as COSV99327941; called by muse, mutect2
- ACAP2 | c.2279T>C p.M760T | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as rs1157829462, COSV58751563; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2964G>C p.Q988H | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV54445800; called by muse, mutect2, varscan2
- AFF2 | c.1943C>A p.P648Q | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53987102; called by muse, mutect2, varscan2
- ASTN2 | c.3781A>T p.R1261W (on ENST00000313400 / NM_001365069.1; = p.R1210W on NM_014010.5) | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV55998438; called by muse, mutect2
- B3GAT1 | c.970A>T p.K324* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | catalogued as COSV56996582; called by muse, mutect2
- CCDC57 | c.2665A>G p.T889A | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.038); catalogued as COSV60754020; called by muse, mutect2, varscan2
- CD163 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.113); catalogued as COSV63131807; called by muse, mutect2
- CDH23 | c.8902G>A p.V2968M | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as rs1179721575, COSV56460736; called by muse, mutect2, varscan2
- CDH7 | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59885262; called by muse, mutect2, varscan2
- CDHR2 | c.2212G>A p.G738S | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as rs1398131203, COSV56138021; called by muse, mutect2, varscan2
- CEP250 | c.2692A>G p.M898V | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61169742; called by muse, mutect2
- CLUL1 | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs775285957, COSV58111866; called by muse, mutect2, varscan2
- CNP | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); catalogued as COSV66367996; called by muse, mutect2
- CNTROB | c.2130G>T p.K710N | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.836); catalogued as COSV66607893, COSV66608066; called by muse, mutect2, varscan2
- CSMD1 | c.3265G>T p.G1089W (on ENST00000520002; = p.G1088W on NM_033225.6) | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59315956; called by muse, mutect2, varscan2
- CSPG4 | c.1922G>T p.R641L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV100414310, COSV57894332; called by muse, mutect2, varscan2
- DOCK2 | c.1123G>T p.G375* | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as COSV99911348; called by muse, mutect2, varscan2
- ERICH3 | c.2429G>T p.R810M | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1383246278, COSV58605426; called by muse, mutect2, varscan2
- F8 | c.2999C>T p.P1000L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV64272740; called by muse, mutect2, varscan2
- FER | c.1844A>G p.Y615C | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55289821; called by muse, mutect2
- FSHR | c.37A>T p.S13C | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.621); catalogued as rs1476467611, COSV58622573; called by muse, mutect2, varscan2
- GBP3 | c.323A>T p.D108V | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52518236; called by muse, mutect2, varscan2
- GJA5 | c.407G>A p.W136* | Nonsense Mutation (SNP) | VAF 10/167 reads (6%) | catalogued as rs1553227002, COSV54782869, COSV54783976; called by muse, mutect2
- GPR158 | c.1567G>T p.G523C | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as COSV66269210; called by muse, mutect2, varscan2
- HHATL | c.1091C>A p.P364Q | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.193); catalogued as COSV55134221; called by muse, varscan2
- HSPA12B | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs769008328, COSV54765599; called by muse, mutect2, varscan2
- IQGAP2 | c.4435G>T p.V1479L | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1266081143, COSV57172501; called by muse, mutect2, varscan2
- KCNAB1 | c.382G>A p.A128T (on ENST00000490337 / NM_172160.3; = p.A117T on NM_003471.3) | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56744848; called by muse, mutect2, varscan2
- KPTN | c.446C>G p.A149G | Missense Mutation (SNP) | VAF 48/302 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV54549862; called by muse, mutect2, varscan2
- KRT40 | c.904C>A p.Q302K | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs1248692567, COSV66696297; called by muse, mutect2, varscan2
- KRTAP19-8 | c.131A>C p.Y44S | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.874); catalogued as COSV66998394; called by muse, mutect2, varscan2
- LRRC30 | c.10A>G p.R4G | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV67301653; called by muse, mutect2
- MUC5B | c.5960C>T p.S1987F | Missense Mutation (SNP) | VAF 48/276 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV71591735; called by muse, mutect2, varscan2
- MYH1 | c.1836C>A p.Y612* | Nonsense Mutation (SNP) | VAF 15/83 reads (18%) | catalogued as COSV99875425; called by muse, mutect2
- MYOF | c.99G>T p.K33N | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1290751479, COSV63703420; called by muse, mutect2
- MYORG | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV52627102; called by muse, mutect2
- NAA25 | c.2788C>T p.L930F | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs749161455, COSV55702780, COSV55704044; called by muse, mutect2, varscan2
- NCAPD2 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV59699085; called by muse, mutect2
- NPAP1 | c.1291G>T p.D431Y | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV61506411; called by muse, mutect2, varscan2
- NRP2 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99783766, COSV99783932; called by muse, mutect2, varscan2
- NUP214 | c.2443C>T p.R815W | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1021262444, COSV63909180; called by muse, mutect2, varscan2
- NXPH4 | c.704T>A p.V235E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61073821; called by muse, mutect2
- OPRL1 | c.1045G>A p.V349M | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs138440707; called by muse, mutect2, varscan2
- OR10AG1 | c.388A>C p.K130Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV56632685; called by muse, mutect2
- OR2T33 | c.790A>G p.R264G | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV58815160; called by muse, mutect2, varscan2
- OR4D10 | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 18/237 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758354478, COSV73260013; called by muse, mutect2
- OR52R1 | c.844C>G p.L282V | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.023); catalogued as COSV61888219; called by muse, mutect2, varscan2
- PBXIP1 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as COSV100870053; called by muse, mutect2, varscan2
- PBXIP1 | c.1026G>T p.E342D | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as rs1236963772, COSV100870055; called by muse, mutect2, varscan2
- PCDH10 | c.1900C>G p.R634G | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); catalogued as COSV52092727, COSV99994699; called by muse, mutect2, varscan2
- PEAR1 | c.2126A>T p.Q709L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV52772696; called by muse, mutect2, varscan2
- PELI2 | c.339C>G p.D113E | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50710812, COSV50710931; called by muse, mutect2, varscan2
- PPIG | c.1814G>T p.R605L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.106); catalogued as COSV53642729, COSV53643521; called by mutect2, varscan2
- PRSS37 | c.473T>G p.M158R | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV63339373; called by muse, mutect2
- PSG8 | c.1157C>A p.T386K | Missense Mutation (SNP) | VAF 61/326 reads (19%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.908); catalogued as COSV60611193; called by muse, mutect2, varscan2
- PTPRS | c.118A>T p.K40* | Nonsense Mutation (SNP) | VAF 16/48 reads (33%) | catalogued as COSV53618239, COSV99512861; called by muse, mutect2, varscan2
- RASAL1 | c.946C>T p.R316W | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as rs763640082, COSV55655580; called by muse, mutect2, varscan2
- RNF144A | c.735G>A p.W245* | Nonsense Mutation (SNP) | VAF 7/109 reads (6%) | catalogued as COSV57982085; called by muse, mutect2
- SMG1 | c.4444G>A p.E1482K | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.972); catalogued as rs749957363, COSV67170946; called by muse, mutect2
- SPTA1 | c.4754T>C p.L1585P | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100934673; called by muse, mutect2, varscan2
- TAP2 | c.609-2A>T p.X203_splice | Splice Site (SNP) | VAF 10/92 reads (11%) | catalogued as COSV66487758; called by muse, mutect2
- TARDBP | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as CM118507, COSV53569709; called by muse, mutect2
- TBX1 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs371125236; called by muse, mutect2, varscan2
- TDRD7 | c.2767C>T p.H923Y | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100795528; called by muse, mutect2, varscan2
- TEX2 | c.2680A>T p.I894F (on ENST00000583097 / NM_001288733.2; = p.I901F on NM_018469.5) | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0.027); catalogued as COSV51980460; called by muse, mutect2, varscan2
- THSD7B | c.417G>C p.Q139H | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55680893; called by muse, mutect2, varscan2
- TNRC6A | c.3166A>T p.S1056C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV59363601; called by muse, mutect2, varscan2
- TONSL | c.2113A>G p.S705G | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV68048176; called by muse, mutect2
- TOR1A | c.357T>G p.I119M | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as COSV61028991; called by muse, mutect2
- TTC25 | c.1076A>C p.K359T | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.147); catalogued as COSV66367991; called by muse, mutect2
- TTN | c.59183C>T p.P19728L (on ENST00000591111; = p.P12304L on NM_003319.4) | Missense Mutation (SNP) | VAF 12/130 reads (9%) | PolyPhen probably damaging (0.999); catalogued as COSV60017517; called by muse, mutect2
- UBE3B | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV55093361; called by muse, mutect2, varscan2
- USH1C | c.1133G>A p.W378* | Nonsense Mutation (SNP) | VAF 107/602 reads (18%) | catalogued as rs550843060, COSV50016452; called by muse, mutect2, varscan2
- WLS | c.1390G>T p.G464C | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV52040184; called by muse, mutect2, varscan2
- WT1 | c.1346C>A p.S449Y | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as CM1311495, COSV100187406, COSV60070752; called by muse, mutect2, varscan2
- ZBTB4 | c.2614G>T p.V872L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV60140040; called by muse, mutect2, varscan2
- ZFHX4 | c.7982G>A p.R2661K | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV50725157, COSV51478022; called by muse, mutect2, varscan2
- ZIC3 | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54973810, COSV54974888; called by muse, mutect2, varscan2
- ZNF248 | c.1112G>T p.R371L | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as COSV61997598; called by muse, mutect2, varscan2
- ZNF28 | c.1397C>A p.P466Q | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV60422071; called by muse, mutect2, varscan2
- ZNF420 | c.1132C>T p.L378F | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as rs1311642255, COSV58493808; called by muse, mutect2, varscan2
- ZNF600 | c.2047C>G p.Q683E | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.135); catalogued as COSV57742409; called by muse, mutect2, varscan2
- ZSCAN1 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs771662377, COSV56603907; called by muse, mutect2, varscan2
- ASTN2 | c.688del p.Q230Sfs*89 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by pindel, varscan2
- CACNA2D2 | c.2879_2880insG p.F960Lfs*10 (on ENST00000479441 / NM_001174051.3; = p.F953Lfs*10 on NM_006030.4) | Frame Shift Ins (INS) | VAF 5/49 reads (10%) | called by mutect2, pindel
- EIF2AK4 | c.2173del p.A725Pfs*66 | Frame Shift Del (DEL) | VAF 18/96 reads (19%) | called by mutect2, varscan2
- FLT3 | c.2545del p.R849Vfs*4 | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | called by mutect2, pindel, varscan2
- RBM10 | c.1701del p.D568Tfs*136 | Frame Shift Del (DEL) | VAF 18/30 reads (60%) | called by mutect2, varscan2
- TMEM163 | c.768A>G p.I256M | Missense Mutation (SNP) | VAF 11/155 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); called by muse, mutect2
- ABCB5 | c.1821T>A p.A607= (on ENST00000404938 / NM_001163941.2; = p.A162= on NM_178559.6) | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV51708426; called by muse, mutect2, varscan2
- ADAMTS2 | c.3585C>A p.I1195= | Silent (SNP) | VAF 13/169 reads (8%) | catalogued as COSV52373580; called by muse, mutect2
- ADNP2 | c.3045G>C p.V1015= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV51538297; called by muse, mutect2, varscan2
- AKAP9 | c.537A>G p.E179= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV62344519; called by muse, mutect2, varscan2
- CACNA1B | c.4797G>T p.L1599= | Silent (SNP) | VAF 32/157 reads (20%) | catalogued as rs1454839501, COSV53124082; called by muse, mutect2, varscan2
- CCZ1B | c.408G>A p.S136= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as rs754203727, COSV100367702, COSV57437093; called by muse, mutect2, varscan2
- ECM1 | c.1323G>C p.L441= | Silent (SNP) | VAF 33/407 reads (8%) | catalogued as COSV60872827; called by muse, mutect2
- ENPP2 | c.1698C>A p.G566= (on ENST00000075322 / NM_001040092.3; = p.G618= on NM_006209.5) | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as COSV50010707; called by muse, mutect2, varscan2
- FAM47C | c.942C>G p.R314= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV63726186; called by muse, mutect2, varscan2
- MAL2 | c.393C>T p.C131= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs753465116, COSV52660906; called by muse, mutect2, varscan2
- MAP3K19 | c.2385C>T p.S795= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV59638401; called by muse, mutect2
- MBD3L1 | c.417C>T p.I139= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV59775898; called by mutect2, varscan2
- MERTK | c.1485G>T p.A495= | Silent (SNP) | VAF 51/241 reads (21%) | catalogued as rs191874938, COSV54928266; called by muse, mutect2, varscan2
- NRP2 | c.396G>T p.G132= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as COSV99783942; called by muse, mutect2, varscan2
- POLR1A | c.2877C>T p.I959= | Silent (SNP) | VAF 15/150 reads (10%) | catalogued as COSV55692293; called by muse, mutect2
- RBM15 | c.174C>T p.S58= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV63923428; called by muse, mutect2, varscan2
- SLC6A7 | c.681C>A p.I227= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as COSV57937980, COSV57940336; called by muse, mutect2, varscan2
- SPTA1 | c.4755G>T p.L1585= | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as COSV100934091, COSV100934672; called by muse, mutect2, varscan2
- TMEM132E | c.1548C>T p.S516= (on ENST00000321639; = p.S606= on NM_001304438.2) | Silent (SNP) | VAF 10/105 reads (10%) | catalogued as rs927360195, COSV58696568; called by muse, mutect2
- TMEM215 | c.159C>T p.G53= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV61363389; called by muse, mutect2, varscan2
- ASS1 | c.773+92G>T | Intron (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- CDH2 | c.173-22606A>T | Intron (SNP) | VAF 36/190 reads (19%) | catalogued as COSV99296363; called by muse, mutect2, varscan2
